Gene-level copy-number profile of tumor specimen TCGA-BW-A5NO-01A from TCGA case TCGA-BW-A5NO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 50.7 years (18,510 days).
Specimen TCGA-BW-A5NO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.f0242e3c-ab3c-4143-97a4-310911353ee5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BW-A5NO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e756282-fcf4-49d4-8ba7-dc8ee4a6e502

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 797; copy number 2: 10,033; copy number 3: 19,480; copy number 4: 24,484; copy number 5: 1,552; copy number 6: 2,350; copy number 7: 395; copy number 8: 423; copy number 10: 39; copy number 11: 263.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BW-A5NO-01A-11D-A27H-01): tumor purity 0.71, ploidy 5.17, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 302 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:43,522,334–43,576,038, 1 gene, copy number 10 (within-gene range 4–10): XPO5.
- chr6:43,576,185–44,830,188, 38 genes, copy number 10: POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1.
- chr15:72,474,330–72,798,199, 15 genes, copy number 11 (within-gene range 3–11): ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1.
- chr17:58,076,891–60,666,280, 110 genes, copy number 11 (broad region; genes not listed).
- chr17:60,696,313–60,851,745, 5 genes, copy number 11: RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28.
- chr17:79,089,345–79,516,148, 1 gene, copy number 11 (within-gene range 4–11): RBFOX3.
- chr17:79,598,032–82,051,831, 132 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 118. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
